Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042943-09A (aliquot TARGET-15-SJMPAL042943-09A-01D) from TARGET case TARGET-15-SJMPAL042943, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.3 years (121 days).
Specimen TARGET-15-SJMPAL042943-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e43fa39-ae81-4760-8d1e-0f27e0c25bcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042943-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042943-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a2ade76-3740-4d52-ba05-e955378352ca

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPTB | c.2274G>T p.W758C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474848178; called by muse, mutect2
- TOP1 | c.628C>A p.R210S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as rs1270296041, COSV63696340; called by muse, mutect2
- BIRC6 | c.9679C>A p.P3227T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- HOXC10 | c.819C>A p.C273* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- KDM3B | c.1594C>A p.Q532K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- STYXL2 | c.2418C>A p.S806R | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.296); called by muse, mutect2
- USE1 | c.741C>A p.S247R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.717); called by muse, mutect2
- TNRC6A | c.1608C>A p.G536= | Silent (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- JAZF1 | c.116-79686C>T | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs1041143642, COSV52240887; called by muse, mutect2
